Gene-level copy-number profile of tumor specimen HTMCP-03-06-02063-01B from CGCI case HTMCP-03-06-02063, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02063-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c39685a3-36eb-4a0b-b83a-b9d10322d644.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02063-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/cb1bc080-4a82-40a3-86cd-fccb5a08722b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 5,758; copy number 2: 39,747; copy number 3: 10,639; copy number 4: 2,124; copy number 5: 83; copy number 6: 17; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,170,775–89,203,906, 6 genes (within-gene range 0–2): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1.
- chr2:89,234,174–89,234,912, 1 gene (within-gene range 0–2): IGKV2-29.
- chr2:89,884,740–89,887,247, 2 genes: IGKV1D-37, IGKV2D-36.
- chr2:89,936,859–89,960,754, 3 genes: IGKV2D-30, IGKV2D-29, IGKV2D-28.
- chr5:816,346–817,001, 1 gene (within-gene range 0–1): SPCS2P3.
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr17:17,456,427–17,457,259, 1 gene: TSEN15P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 103 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,252,211–89,254,015, 2 genes, copy number 5: IGKV3-31, IGKV1-32.
- chr2:89,319,625–89,600,680, 3 genes, copy number 7: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:89,913,982–89,916,052, 1 gene, copy number 5: IGKV1D-33.
- chr3:90,261,414–90,261,708, 1 gene, copy number 5: HSPE1P19.
- chr3:120,908,072–122,892,416, 38 genes, copy number 5: STXBP5L, AC072026.1, MIR5682, AC078857.1, AC079841.1, AC079841.2, POLQ, RPL7AP11, ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P, GOLGB1, IQCB1, EAF2, SLC15A2, ILDR1, Y_RNA, CD86, CASR, HNRNPA1P23, CSTA, CCDC58, FAM162A, WDR5B, AC083798.2, AC083798.1, KPNA1, AC096861.1, PARP9, DTX3L, PARP15, EIF4BP8, PARP14, HSPBAP1, SLC49A4, LINC02035.
- chr6:62,611,153–63,779,336, 17 genes, copy number 6 (within-gene range 2–6): AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr9:64,810,865–66,745,929, 37 genes, copy number 5: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P, CDRT15P12, RBPJP2, RAB28P4, ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr11:48,880,111–48,908,946, 4 genes, copy number 5: AC027369.6, AC027369.3, AC027369.4, AC027369.5.

Autosomal genes at a single copy (total copy number 1): 5,758. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
